Gene-level copy-number profile of tumor specimen HTMCP-02-25-01235-01B from CGCI case HTMCP-02-25-01235, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Dead; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Lung, NOS.
Specimen HTMCP-02-25-01235-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 355bed4d-5635-4f8b-bae0-bb4439224a29.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-25-01235-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/7d1eccdf-b465-47c2-b3a6-4249c9a7aa11

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 17,036; copy number 2: 41,043; copy number 3: 796.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,838,125–12,841,357, 1 gene: PRAMEF30P.
- chr1:12,857,086–12,861,909, 1 gene (within-gene range 0–1): PRAMEF2.
- chr11:89,944,035–90,042,025, 10 genes: AP004607.3, AP004607.9, AP004607.8, AP004607.1, TRIM64, AP004607.7, TRIM51EP, TRIM53AP, AP004607.6, TRIM49C.
- chr15:101,887,354–101,979,093, 11 genes: WBP1LP5, AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr22:21,167,758–21,294,586, 8 genes (within-gene range 0–1): FAM230B, AP000550.2, FAM247A, GGT2, AP000550.3, E2F6P3, POM121L8P, BCRP6.
- chr22:42,500,568–42,519,796, 2 genes: SERHL, RRP7A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 14,180. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
